Somatic mutation profile of tumor specimen MP2PRT-PAPWDY-TMP1-A (aliquot MP2PRT-PAPWDY-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPWDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (706 days).
Specimen MP2PRT-PAPWDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11d0a6a6-53b3-4dff-87ed-f3720814531b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWDY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWDY-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c2a9b69-a3b4-48d0-a97b-b9be273c87c9

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 50/432 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCUBE1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs372229798; called by muse, mutect2, varscan2
- ACRBP | c.1597_1604del p.E533Hfs*29 | Frame Shift Del (DEL) | VAF 59/360 reads (16%) | called by mutect2, pindel, varscan2
- H3C4 | c.135_139del p.T46Gfs*27 | Frame Shift Del (DEL) | VAF 40/433 reads (9%) | called by mutect2, pindel
- SCEL | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAAH2 | c.1206A>C p.S402= | Silent (SNP) | VAF 50/191 reads (26%) | called by muse, mutect2, varscan2
- FRAS1 | c.8412C>A p.G2804= | Silent (SNP) | VAF 22/291 reads (8%) | called by muse, mutect2
- NCAPD3 | c.2538G>T p.G846= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- XKR7 | c.1419C>A p.P473= | Silent (SNP) | VAF 41/573 reads (7%) | called by muse, mutect2
